Somatic mutation profile of tumor specimen TCGA-EB-A3XC-01A (aliquot TCGA-EB-A3XC-01A-11D-A23B-08) from TCGA case TCGA-EB-A3XC, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 74.3 years (27,124 days).
Specimen TCGA-EB-A3XC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4001d062-2a29-4727-9625-9aea545ac80e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A3XC-10A (Blood Derived Normal), aliquot TCGA-EB-A3XC-10A-01D-A23B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb860ae5-f342-414b-89d1-db6bd4d816a9

The open-access MAF lists 494 somatic variants for this specimen: 321 protein-altering or splice-affecting, 159 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 287, Silent 159, Nonsense Mutation 13, Splice Region 11, Splice Site 6, Intron 6, RNA 4, 3'UTR 3, Frame Shift Del 2, 5'UTR 1, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>G p.V640G (on ENST00000288602 / NM_001374244.1; = p.V600G on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 108/294 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 106/296 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- IL7R | c.1184A>C p.K395T | Missense Mutation (SNP) | VAF 6/51 reads (12%) | hotspot (GDC flag); SIFT tolerated (0.46); PolyPhen benign (0.029); catalogued as COSV57406142, COSV57406506, COSV57407763; called by muse, mutect2, varscan2
- TP53 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 26/30 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AADACL2 | c.918T>G p.S306R | Missense Mutation (SNP) | VAF 52/312 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.222); catalogued as COSV62931088; called by muse, mutect2, varscan2
- ABCA9 | c.576C>T p.I192= | Splice Region (SNP) | VAF 35/87 reads (40%) | catalogued as rs777966131, COSV100383290, COSV60627123; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.946A>G p.R316G | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV68344182; called by muse, mutect2, varscan2
- AC004922.1 | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 93/199 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.605); catalogued as COSV53557728; called by muse, mutect2, varscan2
- AC006059.2 | c.1961A>G p.N654S | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV59607906; called by muse, mutect2, varscan2
- AC013489.1 | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.79); PolyPhen benign (0.022); catalogued as rs377259359; called by muse, mutect2, varscan2
- ACKR4 | c.938A>T p.Y313F | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV51442795; called by muse, mutect2, varscan2
- ACSL6 | c.1785C>T p.A595= (on ENST00000379240; = p.A620= on NM_015256.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 21/36 reads (58%) | catalogued as COSV57296360, COSV57300619; called by muse, mutect2, varscan2
- ADAMTS7 | c.3238C>T p.P1080S | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV66308085; called by muse, mutect2, varscan2
- ADCY6 | c.281C>T p.T94I | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV57168779; called by muse, mutect2, varscan2
- ADCY8 | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 88/207 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867747553, COSV53897387; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1047-1G>A p.X349_splice | Splice Site (SNP) | VAF 28/362 reads (8%) | catalogued as COSV100416146; called by muse, mutect2
- ADCYAP1R1 | c.1047G>A p.L349= | Splice Region (SNP) | VAF 28/358 reads (8%) | catalogued as COSV100416147; called by muse, mutect2
- ADGRD1 | c.2357T>A p.V786D | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV55449207; called by muse, mutect2
- ADGRV1 | c.18043C>T p.L6015F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as COSV101315989, COSV67988744; called by muse, mutect2, varscan2
- AHNAK2 | c.15259C>T p.L5087F | Missense Mutation (SNP) | VAF 71/184 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as COSV60920058; called by muse, mutect2, varscan2
- ALMS1 | c.8929G>A p.D2977N | Missense Mutation (SNP) | VAF 47/276 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV52513461; called by muse, mutect2, varscan2
- ALS2CL | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs753736240, COSV59672158; called by muse, mutect2, varscan2
- AMPH | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 122/256 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV57747181; called by muse, mutect2, varscan2
- ANKAR | c.511T>C p.F171L | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); catalogued as COSV55614670; called by muse, mutect2, varscan2
- ANKRD30A | c.3328G>A p.E1110K (on ENST00000611781; = p.E1054K on NM_052997.2) | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs267602485, COSV64603763; called by muse, mutect2, varscan2
- ANKS4B | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61139494; called by muse, mutect2, varscan2
- ANKS4B | c.815G>A p.G272E | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61139505; called by muse, mutect2, varscan2
- ANO4 | c.558G>A p.R186= (on ENST00000392977 / NM_001286615.2; = p.R151= on NM_178826.4) | Splice Region (SNP) | VAF 53/181 reads (29%) | catalogued as COSV54591525; called by muse, mutect2, varscan2
- AP3B2 | c.2218G>A p.E740K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.056); catalogued as rs1294295444, COSV55611114; called by muse, mutect2, varscan2
- APP | c.573A>C p.E191D | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV61000476; called by muse, mutect2, varscan2
- ARHGEF10 | c.3297G>A p.E1099= (on ENST00000398564; = p.E1074= on NM_014629.4) | Splice Region (SNP) | VAF 20/59 reads (34%) | catalogued as COSV50701126; called by muse, mutect2, varscan2
- ARHGEF10 | c.3297+1G>A p.X1099_splice (on ENST00000398564; = p.X1074_splice on NM_014629.4) | Splice Site (SNP) | VAF 19/60 reads (32%) | catalogued as COSV100033650; called by muse, mutect2, varscan2
- ARMC2 | c.2269G>A p.G757R | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.906); catalogued as COSV100933482, COSV64551852; called by muse, mutect2, varscan2
- ASTN2 | c.2641C>G p.L881V (on ENST00000313400 / NM_001365069.1; = p.L830V on NM_014010.5) | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.88); catalogued as COSV57791209; called by muse, mutect2, varscan2
- BICD1 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 69/183 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55682048; called by muse, mutect2, varscan2
- BIRC6 | c.6542A>G p.Y2181C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1462254676, COSV70201884; called by muse, mutect2
- C10orf71 | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 57/93 reads (61%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.521); catalogued as COSV60509449; called by muse, mutect2, varscan2
- C11orf80 | c.471C>G p.F157L | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.657); catalogued as COSV60929840; called by muse, mutect2, varscan2
- C14orf39 | c.334C>T p.H112Y | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58783080; called by muse, mutect2, varscan2
- C16orf78 | c.91C>G p.L31V | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54557055; called by muse, mutect2, varscan2
- C1S | c.1727G>A p.R576K | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV61071311; called by muse, mutect2, varscan2
- C1orf127 | c.1961G>A p.G654E | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.422); catalogued as COSV65437764; called by muse, mutect2, varscan2
- CA1 | c.11C>A p.P4Q | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as rs758858882, COSV56279104; called by muse, mutect2, varscan2
- CACNA2D1 | c.2459C>T p.S820F (on ENST00000356253 / NM_001366867.1; = p.S808F on NM_000722.4) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV62383391; called by muse, mutect2, varscan2
- CADPS2 | c.1843G>T p.A615S | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV57370913; called by muse, mutect2, varscan2
- CAPG | c.188T>G p.L63R | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as COSV55707923; called by muse, mutect2, varscan2
- CASC3 | c.1568C>T p.S523L | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52868165; called by muse, mutect2, varscan2
- CASP8AP2 | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 83/171 reads (49%) | catalogued as COSV52748197, COSV52750135; called by muse, mutect2, varscan2
- CBLB | c.1598C>T p.S533F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1292648481, COSV51430030; called by muse, mutect2, varscan2
- CBX2 | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as COSV53969448; called by muse, mutect2, varscan2
- CCDC185 | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.144); catalogued as COSV64821246; called by muse, mutect2, varscan2
- CCDC74A | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV54606747; called by muse, mutect2, varscan2
- CCDC74A | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV99723526; called by muse, mutect2, varscan2
- CDH1 | c.2396C>T p.P799L | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as CM041267, COSV99931151; called by muse, mutect2, varscan2
- CHRNA10 | c.752C>T p.S251L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs763375115, COSV51705491; called by muse, mutect2, varscan2
- COL3A1 | c.3538C>T p.H1180Y | Missense Mutation (SNP) | VAF 100/196 reads (51%) | SIFT tolerated (1); PolyPhen possibly damaging (0.486); catalogued as COSV100483572, COSV58591429; called by muse, mutect2, varscan2
- COL9A2 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776441743, COSV65607736; called by muse, mutect2, varscan2
- CRAMP1 | c.2656C>T p.P886S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99245556; called by muse, mutect2, varscan2
- CRAMP1 | c.2657C>T p.P886L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99245558; called by muse, mutect2, varscan2
- CRMP1 | c.292G>T p.V98L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV61481255; called by muse, mutect2, varscan2
- CYP11B1 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs200711326, COSV52828441; called by muse, mutect2, varscan2
- DCC | c.1182T>G p.D394E | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59113176; called by muse, mutect2, varscan2
- DCHS1 | c.4862C>T p.A1621V | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.426); catalogued as rs1208922258, COSV55038202; called by muse, mutect2, varscan2
- DDX60 | c.2491C>T p.R831C | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs778806064, COSV67095443; called by muse, mutect2, varscan2
- DEFA6 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV52406223; called by muse, mutect2, varscan2
- DHX9 | c.1507C>T p.R503* | Nonsense Mutation (SNP) | VAF 114/296 reads (39%) | catalogued as COSV62360398; called by muse, mutect2, varscan2
- DNAH10 | c.1489G>A p.A497T (on ENST00000409039; = p.A436T on NM_207437.3) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV68996200; called by muse, mutect2, varscan2
- DNAH3 | c.8872G>A p.E2958K | Missense Mutation (SNP) | VAF 160/334 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV54531189; called by muse, mutect2, varscan2
- DNAH3 | c.5809G>A p.E1937K | Missense Mutation (SNP) | VAF 71/147 reads (48%) | SIFT tolerated (0.87); PolyPhen benign (0.202); catalogued as COSV54530540; called by muse, mutect2, varscan2
- DNAH3 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 53/188 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs866290636, COSV54531212; called by muse, mutect2, varscan2
- DNAH7 | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as COSV56771867; called by muse, mutect2, varscan2
- DOLPP1 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59910636; called by muse, mutect2, varscan2
- DPH2 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.637); catalogued as COSV52543973; called by muse, mutect2, varscan2
- DSCAM | c.2311G>A p.D771N | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.12); catalogued as rs267606128, COSV68029375; called by muse, mutect2, varscan2
- DYNC2H1 | c.10562C>T p.A3521V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV62098203; called by muse, mutect2, varscan2
- EDEM3 | c.838G>C p.D280H | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV58925546; called by muse, mutect2, varscan2
- EGFLAM | c.707C>T p.T236I | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.672); catalogued as rs755435692, COSV59307391; called by muse, mutect2, varscan2
- ELF5 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 19/70 reads (27%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV56629576; called by muse, mutect2, varscan2
- ENKUR | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs751596707, COSV58633319; called by muse, mutect2, varscan2
- ENPP4 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 98/225 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); catalogued as rs766472788, COSV58088752; called by muse, mutect2, varscan2
- EPB41L2 | c.1019C>G p.T340S | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV61356828; called by muse, mutect2, varscan2
- FAM104A | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs746061460, COSV52147396; called by muse, mutect2, varscan2
- FAM120AOS | c.287C>G p.P96R | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs1391593993, COSV52906986; called by muse, mutect2, varscan2
- FAM135B | c.1071A>C p.Q357H | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as rs1382278780, COSV52735173; called by muse, mutect2, varscan2
- FAM155A | c.817C>T p.H273Y | Missense Mutation (SNP) | VAF 60/106 reads (57%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.453); catalogued as rs758059010, COSV101026577; called by muse, mutect2, varscan2
- FAM217B | c.1060G>A p.G354R | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV62564412; called by muse, mutect2, varscan2
- FASTKD1 | c.873G>T p.K291N | Missense Mutation (SNP) | VAF 33/317 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV70006587; called by muse, mutect2, varscan2
- FAT3 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53118505, COSV53133288; called by muse, mutect2, varscan2
- FAT3 | c.6262C>A p.P2088T | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53133318; called by muse, mutect2, varscan2
- FCRL5 | c.2476G>A p.G826R | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as COSV62511447; called by muse, mutect2, varscan2
- FGD2 | c.829C>G p.L277V | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51464408; called by muse, mutect2, varscan2
- FGD5 | c.4369G>A p.E1457K | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.429); catalogued as COSV53246171; called by muse, mutect2, varscan2
- FIP1L1 | c.875T>C p.V292A | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV60997684; called by muse, mutect2, varscan2
- FKBP9 | c.1174C>T p.L392F | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV54232388, COSV54233875; called by muse, mutect2, varscan2
- FLG | c.2047C>T p.R683C | Missense Mutation (SNP) | VAF 290/829 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs149385928; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.731T>G p.V244G | Missense Mutation (SNP) | VAF 23/308 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.71); catalogued as COSV58558444, COSV58562185; called by muse, mutect2
- FREM2 | c.154G>A p.G52S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.013); catalogued as COSV99746613; called by muse, mutect2, varscan2
- FREM2 | c.155G>A p.G52D | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); catalogued as COSV99746615; called by muse, mutect2, varscan2
- FRG2C | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 47/240 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs267599932; called by muse, mutect2, varscan2
- FSD2 | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 139/440 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58010990; called by muse, mutect2, varscan2
- FTMT | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as COSV58420682; called by muse, mutect2, varscan2
- GALNT13 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 154/548 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs865891391, COSV67214066; called by muse, mutect2, varscan2
- GART | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV63113561; called by muse, mutect2, varscan2
- GCN1 | c.896T>G p.I299S | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV56110120; called by muse, mutect2, varscan2
- GIMAP5 | c.785A>T p.E262V | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV57530125; called by muse, mutect2, varscan2
- GIMAP6 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 24/378 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs774846551, COSV61033479; called by muse, mutect2
- GLRB | c.402G>T p.M134I | Missense Mutation (SNP) | VAF 67/148 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.423); catalogued as COSV52418670; called by muse, mutect2, varscan2
- GLYAT | c.657G>A p.W219* | Nonsense Mutation (SNP) | VAF 59/172 reads (34%) | catalogued as COSV53538316, COSV53539760; called by muse, mutect2
- GPRC6A | c.2763A>C p.K921N | Missense Mutation (SNP) | VAF 50/246 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV59953895; called by muse, mutect2, varscan2
- GRIN3A | c.2238G>A p.M746I | Missense Mutation (SNP) | VAF 155/205 reads (76%) | SIFT tolerated (0.07); PolyPhen benign (0.351); catalogued as COSV62455569; called by muse, mutect2, varscan2
- GRM8 | c.1781G>A p.G594E | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58840245; called by muse, mutect2, varscan2
- GTSE1 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.519); catalogued as COSV71889360; called by muse, mutect2, varscan2
- HCN1 | c.2296G>A p.E766K | Missense Mutation (SNP) | VAF 42/61 reads (69%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.014); catalogued as rs776567935, COSV57499129; called by muse, mutect2, varscan2
- HDAC9 | c.1697G>A p.G566E | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.091); catalogued as COSV67776938; called by muse, mutect2, varscan2
- HECTD3 | c.1984T>G p.F662V | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV64670433; called by muse, mutect2
- HFM1 | c.1408C>T p.L470F | Missense Mutation (SNP) | VAF 93/175 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV54030751; called by muse, mutect2, varscan2
- HIPK2 | c.1976C>T p.P659L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61229496; called by muse, mutect2, varscan2
- HIRA | c.860A>G p.N287S | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV54276511; called by muse, mutect2, varscan2
- HSF2BP | c.37-1G>A p.X13_splice | Splice Site (SNP) | VAF 13/90 reads (14%) | catalogued as COSV52357609; called by muse, mutect2, varscan2
- HTR5A | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 117/277 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs753684277, COSV55282760, COSV55286022; called by muse, mutect2, varscan2
- HUNK | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV54230679; called by muse, mutect2, varscan2
- HUWE1 | c.5531C>T p.S1844L | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV53352311; called by muse, mutect2, varscan2
- HYDIN | c.6662G>A p.R2221Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201209591, COSV59261776; called by muse, mutect2, varscan2
- IFT88 | c.1654A>G p.K552E (on ENST00000319980 / NM_001318493.2; = p.K543E on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/53 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60674693; called by muse, mutect2, varscan2
- IGHV6-1 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 107/261 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.911); catalogued as rs543799892; called by muse, mutect2, varscan2
- IL1R2 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 77/333 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.618); catalogued as rs371567278; called by muse, mutect2, varscan2
- INPP5D | c.2950C>T p.L984F (on ENST00000445964 / NM_001017915.3; = p.L983F on NM_005541.5) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.063); catalogued as COSV64038141; called by muse, mutect2, varscan2
- IPO13 | c.2102T>C p.V701A | Missense Mutation (SNP) | VAF 94/242 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV64894643; called by muse, mutect2, varscan2
- IQCH | c.2318G>A p.G773E | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1567174393, COSV60055450; called by muse, mutect2, varscan2
- IQGAP3 | c.1930C>T p.P644S | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.058); catalogued as rs747202672, COSV63249636; called by muse, mutect2, varscan2
- IRAG1 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs1282735373, COSV70211831; called by muse, mutect2
- IRF6 | c.899G>A p.R300K | Missense Mutation (SNP) | VAF 62/127 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65418722, COSV65419361; called by muse, mutect2, varscan2
- ITGA10 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs782794751, COSV65197987; called by muse, mutect2, varscan2
- ITGAE | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 74/116 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV53996150; called by muse, mutect2, varscan2
- ITGBL1 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); catalogued as rs1402234251, COSV66024437; called by muse, mutect2, varscan2
- ITGBL1 | c.793C>T p.H265Y | Missense Mutation (SNP) | VAF 44/294 reads (15%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.869); catalogued as COSV66006401; called by muse, mutect2, varscan2
- ITPRID1 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.382); catalogued as rs566678979, COSV60072195; called by muse, mutect2
- KAT2A | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs782651040, COSV52426710; called by muse, mutect2, varscan2
- KCNA10 | c.973C>T p.Q325* | Nonsense Mutation (SNP) | VAF 85/246 reads (35%) | catalogued as rs1207987332, COSV63904885; called by muse, mutect2, varscan2
- KCNB1 | c.1340C>T p.S447F | Missense Mutation (SNP) | VAF 94/305 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV65569169; called by muse, mutect2, varscan2
- KCNF1 | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.691); catalogued as COSV54464224; called by muse, mutect2, varscan2
- KCNT1 | c.439C>T p.P147S (on ENST00000488444; = p.P166S on NM_020822.3) | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV53704435; called by muse, mutect2, varscan2
- KLB | c.100G>C p.G34R | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs748780456, COSV57302727; called by muse, mutect2, varscan2
- KLHL38 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1231113129, COSV58088005; called by muse, mutect2, varscan2
- KLHL4 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 65/87 reads (75%) | catalogued as rs1476085711, COSV64144168; called by muse, mutect2, varscan2
- KLK6 | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59566008; called by muse, mutect2, varscan2
- KMT2C | c.2908G>A p.A970T | Missense Mutation (SNP) | VAF 68/1084 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV51337464, COSV51429757; called by muse, mutect2
- LATS1 | c.2942C>T p.A981V | Missense Mutation (SNP) | VAF 80/185 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV53593622; called by muse, mutect2, varscan2
- LELP1 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.158); catalogued as COSV64202542, COSV64202608; called by muse, mutect2, varscan2
- LGR5 | c.425C>T p.S142F | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57002907; called by muse, mutect2, varscan2
- LGR5 | c.426C>T p.S142= | Splice Region (SNP) | VAF 26/144 reads (18%) | catalogued as rs960652775, COSV57002177; called by muse, mutect2, varscan2
- LMO2 | c.304C>T p.R102C (on ENST00000395833 / NM_001142315.2; = p.R171C on NM_005574.4) | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1438345549, COSV57645538; called by muse, mutect2, varscan2
- MACC1 | c.938G>A p.S313N | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as COSV60544238; called by muse, mutect2, varscan2
- MAGEB3 | c.619C>T p.L207F | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV64397343; called by muse, mutect2, varscan2
- MDC1 | c.3415C>T p.P1139S | Missense Mutation (SNP) | VAF 141/349 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.135); catalogued as rs1166716221, COSV64525215; called by muse, mutect2, varscan2
- MEFV | c.1878G>A p.W626* | Nonsense Mutation (SNP) | VAF 86/432 reads (20%) | catalogued as COSV54823938; called by muse, mutect2, varscan2
- MGAT4C | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs1222715246, COSV59830124, COSV59831777; called by muse, mutect2, varscan2
- MMP19 | c.1511C>A p.T504N | Missense Mutation (SNP) | VAF 116/317 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as COSV59451953; called by muse, mutect2, varscan2
- MPIG6B | c.194G>A p.W65* | Nonsense Mutation (SNP) | VAF 44/124 reads (35%) | catalogued as COSV65389863; called by muse, mutect2, varscan2
- MRAP2 | c.288A>T p.R96S | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.068); catalogued as rs1175341909, COSV57633060; called by muse, mutect2, varscan2
- MS4A4A | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.051); catalogued as COSV59701903; called by muse, mutect2, varscan2
- MSH5 | c.1579T>C p.S527P | Missense Mutation (SNP) | VAF 65/129 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV65210264; called by muse, mutect2, varscan2
- MUC16 | c.41554G>A p.D13852N | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated, low confidence (0.36); PolyPhen probably damaging (0.968); catalogued as COSV66693906; called by muse, mutect2, varscan2
- MUC16 | c.7150G>A p.D2384N | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV67468153; called by muse, mutect2, varscan2
- MUC16 | c.3871C>T p.H1291Y | Missense Mutation (SNP) | VAF 128/303 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); catalogued as COSV67451827; called by muse, mutect2, varscan2
- MUC6 | c.4238G>A p.G1413E | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.012); catalogued as rs1554897504, COSV70144436; called by muse, mutect2, varscan2
- MYCBPAP | c.2638G>A p.D880N | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.361); catalogued as COSV52140877; called by muse, mutect2, varscan2
- MYH11 | c.4539G>A p.M1513I | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.792); catalogued as COSV55558565; called by muse, mutect2, varscan2
- MYH8 | c.2429G>T p.R810M | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV67967700; called by muse, mutect2, varscan2
- MYO5B | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as COSV53222716; called by muse, mutect2, varscan2
- NCK2 | c.799C>G p.P267A | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV51892820; called by muse, mutect2, varscan2
- NCKAP5 | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 7/17 reads (41%) | catalogued as COSV58454726; called by muse, mutect2, varscan2
- NDE1 | c.733C>T p.L245F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV61272291, COSV61273690; called by muse, mutect2, varscan2
- NEB | c.6217G>A p.G2073R | Missense Mutation (SNP) | VAF 129/257 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51079468; called by muse, mutect2, varscan2
- NEBL | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV65840059; called by muse, mutect2, varscan2
- NEK1 | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV71456640; called by muse, varscan2
- NEK10 | c.69C>T p.I23= | Splice Region (SNP) | VAF 17/65 reads (26%) | catalogued as COSV58285607; called by muse, mutect2, varscan2
- NELL1 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 79/194 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV54283572; called by muse, mutect2, varscan2
- NFIA | c.37C>T p.H13Y | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV64539972; called by muse, mutect2, varscan2
- NFRKB | c.2039C>T p.P680L (on ENST00000446488 / NM_001143835.2; = p.P705L on NM_006165.3) | Missense Mutation (SNP) | VAF 154/300 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV58758828; called by muse, mutect2, varscan2
- NGDN | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV68142555; called by muse, mutect2, varscan2
- NOVA1 | c.393A>C p.E131D | Missense Mutation (SNP) | VAF 27/245 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV57474764, COSV57478209; called by muse, mutect2, varscan2
- NPC1L1 | c.3746C>T p.P1249L | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56926717; called by muse, mutect2
- NRXN3 | c.2408G>A p.G803E (on ENST00000335750 / NM_001330195.2; = p.G430E on NM_004796.6) | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59768005; called by muse, mutect2, varscan2
- NT5C1A | c.558G>A p.G186= | Splice Region (SNP) | VAF 18/51 reads (35%) | catalogued as COSV52493092; called by muse, mutect2, varscan2
- OCEL1 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52244244; called by muse, mutect2, varscan2
- OGA | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 66/121 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63382210; called by muse, mutect2, varscan2
- OIT3 | c.1292G>A p.S431N | Missense Mutation (SNP) | VAF 42/66 reads (64%) | SIFT tolerated (0.18); PolyPhen benign (0.346); catalogued as COSV61826579; called by muse, mutect2, varscan2
- OR11H1 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV99421539; called by mutect2, varscan2
- OR2A25 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 92/219 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV68717382; called by muse, mutect2, varscan2
- OR2A25 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 257/630 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0.021); catalogued as rs1395954638, COSV68717387; called by muse, mutect2, varscan2
- OR2B2 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs916095940, COSV100308235, COSV57580039; called by muse, mutect2
- OR2C3 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV63575421; called by muse, mutect2, varscan2
- OR2G6 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 68/219 reads (31%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as COSV100598317, COSV58574066; called by muse, mutect2, varscan2
- OR4D11 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 135/326 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57586192, COSV57586542, COSV57587462; called by muse, mutect2, varscan2
- OR4K1 | c.460C>T p.L154F | Missense Mutation (SNP) | VAF 59/314 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.111); catalogued as rs1479982265, COSV53460888, COSV53462460; called by muse, mutect2, varscan2
- OR51A4 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as COSV66749489; called by muse, mutect2, varscan2
- OR51S1 | c.643G>A p.G215S | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV59059034; called by muse, mutect2, varscan2
- OR52E4 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57625284; called by muse, mutect2, varscan2
- OR6C75 | c.296T>C p.L99P | Missense Mutation (SNP) | VAF 86/227 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV58552625; called by mutect2, varscan2
- OR8D1 | c.820T>A p.S274T | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV63442598; called by muse, mutect2
- OXCT2 | c.897G>C p.R299S | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59594159; called by muse, mutect2, varscan2
- P2RY14 | c.987T>G p.N329K | Missense Mutation (SNP) | VAF 83/244 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.125); catalogued as COSV56384749; called by muse, mutect2, varscan2
- PAK5 | c.2050G>A p.E684K | Missense Mutation (SNP) | VAF 85/286 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs867360779, COSV100781221, COSV62030929; called by muse, mutect2, varscan2
- PATJ | c.2887G>A p.G963R | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.618); catalogued as COSV57165535; called by muse, mutect2, varscan2
- PCDHB14 | c.1846G>A p.G616S | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.017); catalogued as rs201211545, COSV99505496; called by muse, mutect2, varscan2
- PCDHB5 | c.1153C>T p.Q385* | Nonsense Mutation (SNP) | VAF 23/91 reads (25%) | catalogued as COSV99167593; called by muse, mutect2, varscan2
- PCF11 | c.1776G>T p.K592N | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV53533657; called by muse, mutect2, varscan2
- PCLO | c.4982G>A p.G1661E | Missense Mutation (SNP) | VAF 106/275 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61627450, COSV61662677; called by muse, mutect2, varscan2
- PDE7B | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57501365; called by muse, mutect2, varscan2
- PDGFB | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as rs776409973, COSV58648065; called by muse, mutect2, varscan2
- PDYN | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV54100904; called by muse, mutect2, varscan2
- PHLDB2 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV67313007; called by muse, mutect2, varscan2
- PIK3C2G | c.1993C>T p.Q665* (on ENST00000676171; = p.Q624* on NM_004570.5) | Nonsense Mutation (SNP) | VAF 13/114 reads (11%) | catalogued as COSV56815887; called by muse, mutect2, varscan2
- PKP2 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs765756156, COSV50734849; called by muse, mutect2, varscan2
- PLCB4 | c.2609C>T p.S870F | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as COSV53806752; called by muse, mutect2, varscan2
- PLCL2 | c.1406G>A p.S469N (on ENST00000615277 / NM_001144382.2; = p.S343N on NM_015184.5) | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV67623097; called by muse, mutect2
- PLEKHH1 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV61284947; called by muse, mutect2
- PLK2 | c.1393G>A p.D465N | Missense Mutation (SNP) | VAF 59/97 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV57108255; called by muse, mutect2, varscan2
- PLXNA2 | c.5254A>G p.I1752V | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.851); catalogued as COSV65442054; called by muse, mutect2, varscan2
- POLG2 | c.283T>C p.C95R | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV56750035; called by muse, mutect2, varscan2
- PPP6C | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 63/86 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65207922; called by muse, mutect2, varscan2
- PRKCH | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV60647171, COSV60649626; called by muse, mutect2, varscan2
- PROCR | c.623A>T p.Y208F | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.132); catalogued as COSV53826166; called by muse, mutect2, varscan2
- PRRC2A | c.2386T>C p.F796L | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV65687610; called by muse, mutect2
- PRSS12 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 74/140 reads (53%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV56607463; called by muse, mutect2, varscan2
- PTK7 | c.1522C>T p.P508S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100029801; called by muse, mutect2, varscan2
- PTPN23 | c.2395C>T p.P799S | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV55545745; called by muse, mutect2, varscan2
- PTPRB | c.282G>C p.R94S | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.202); catalogued as COSV54245029, COSV99716880; called by muse, mutect2, varscan2
- PXDN | c.3368G>A p.G1123E | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53238799; called by muse, mutect2, varscan2
- RAD51 | c.644G>A p.R215K | Missense Mutation (SNP) | VAF 88/141 reads (62%) | SIFT tolerated (0.19); PolyPhen benign (0.158); catalogued as COSV51112274; called by muse, mutect2, varscan2
- RADIL | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.592); catalogued as COSV101271231; called by muse, mutect2, varscan2
- RALGAPA2 | c.4253T>A p.F1418Y | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV52501900; called by muse, mutect2, varscan2
- RASGRP3 | c.500C>G p.S167C | Missense Mutation (SNP) | VAF 119/297 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV67822987; called by muse, mutect2, varscan2
- RBBP8 | c.1598C>T p.S533F | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs1245273912, COSV59090882; called by muse, mutect2, varscan2
- RBMS1 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV62354414; called by muse, mutect2, varscan2
- RBSN | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV99514967; called by muse, mutect2, varscan2
- RELN | c.10330G>A p.G3444R | Missense Mutation (SNP) | VAF 60/231 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.997); catalogued as COSV59013089; called by muse, mutect2, varscan2
- RELN | c.5552C>T p.S1851L | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV59013101; called by muse, mutect2, varscan2
- RGS7 | c.1247G>T p.R416L | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100464246, COSV58537660; called by muse, mutect2, varscan2
- RIF1 | c.469G>A p.V157I | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1377370709, COSV54619281; called by muse, mutect2, varscan2
- RNF32 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 26/378 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1214398414, COSV58731387, COSV58733331; called by muse, mutect2
- RNF6 | c.1778T>A p.L593* | Nonsense Mutation (SNP) | VAF 105/202 reads (52%) | catalogued as COSV60419447; called by muse, mutect2, varscan2
- RPS6KA1 | c.2102C>T p.T701M | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs367842246; called by muse, varscan2
- RSPH10B | c.1748G>A p.W583* | Nonsense Mutation (SNP) | VAF 78/320 reads (24%) | catalogued as COSV100521197; called by muse, mutect2, varscan2
- RSPH9 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 192/491 reads (39%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs1189173944, COSV64664665; called by muse, mutect2, varscan2
- RUNX1T1 | c.712G>A p.E238K (on ENST00000265814 / NM_001198628.1; = p.E211K on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as rs746997350, COSV56139578; called by muse, mutect2, varscan2
- SACS | c.5496T>G p.F1832L | Missense Mutation (SNP) | VAF 76/153 reads (50%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.535); catalogued as COSV66542557; called by muse, mutect2, varscan2
- SAP130 | c.2053G>C p.E685Q | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV52098397, COSV52099163; called by muse, mutect2, varscan2
- SCG3 | c.1208G>A p.G403E | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV55021884; called by muse, mutect2, varscan2
- SDK1 | c.6243C>A p.N2081K | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67376390, COSV67389036; called by muse, mutect2, varscan2
- SEMA3E | c.696G>A p.M232I | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.062); catalogued as COSV57096773; called by muse, mutect2, varscan2
- SEMA3G | c.1433A>G p.E478G | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51596588; called by muse, mutect2, varscan2
- SGIP1 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 129/346 reads (37%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.146); catalogued as COSV52767941; called by muse, mutect2, varscan2
- SKIV2L | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs765221177, COSV64812531; called by muse, mutect2, varscan2
- SLC2A5 | c.542G>A p.G181D | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1445787696, COSV66237243; called by muse, mutect2, varscan2
- SLC38A4 | c.950G>A p.S317N | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV56968712; called by muse, mutect2, varscan2
- SLC6A11 | c.1551G>A p.M517I | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV54395377; called by muse, mutect2, varscan2
- SLC6A14 | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 59/91 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV64147639; called by muse, mutect2, varscan2
- SLC8A1 | c.1910A>C p.K637T | Missense Mutation (SNP) | VAF 19/389 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV60479215; called by muse, mutect2
- SLCO1B3 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 99/266 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV53932962, COSV53944569; called by muse, mutect2, varscan2
- SMCHD1 | c.2480C>T p.S827L | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV55260922; called by muse, mutect2, varscan2
- SMPD2 | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.183); catalogued as COSV99237713; called by muse, mutect2, varscan2
- SORL1 | c.2710C>T p.R904W | Missense Mutation (SNP) | VAF 90/171 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148966249; called by muse, mutect2, varscan2
- SPEN | c.5182C>G p.P1728A | Missense Mutation (SNP) | VAF 114/370 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV65363865; called by muse, mutect2, varscan2
- SPINK5 | c.1636G>A p.D546N | Missense Mutation (SNP) | VAF 54/91 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56249822, COSV56264012; called by muse, mutect2, varscan2
- SRRM1 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.219); catalogued as COSV60478508; called by muse, mutect2, varscan2
- SRRM1 | c.1681C>T p.P561S | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.992); catalogued as COSV60478528; called by muse, mutect2, varscan2
- STK32B | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.45); catalogued as COSV51496100; called by muse, mutect2, varscan2
- STON1 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 103/410 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59128703, COSV59132849; called by muse, mutect2, varscan2
- SYMPK | c.2861C>T p.S954F | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV55610075; called by muse, mutect2, varscan2
- SYNJ2 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 57/256 reads (22%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.993); catalogued as COSV62898485; called by muse, mutect2, varscan2
- SZT2 | c.7427G>A p.R2476Q (on ENST00000634258 / NM_001365999.1; = p.R2419Q on NM_015284.4) | Missense Mutation (SNP) | VAF 80/201 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100986969, COSV65171191; called by muse, mutect2, varscan2
- TANC1 | c.2492C>T p.A831V | Missense Mutation (SNP) | VAF 87/159 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV55090882; called by muse, mutect2, varscan2
- TBC1D20 | c.151A>G p.R51G | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV62612381, COSV62613063; called by muse, mutect2, varscan2
- TBX10 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 105/329 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.391); catalogued as COSV56875943; called by muse, mutect2, varscan2
- TENM3 | c.6658G>A p.G2220S | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1439322633, COSV69312367; called by muse, mutect2, varscan2
- TF | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as COSV53921329, COSV99395317; called by muse, mutect2, varscan2
- THSD7A | c.3728G>A p.G1243E | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69855865; called by muse, mutect2, varscan2
- TLK2 | c.154-1G>A p.X52_splice | Splice Site (SNP) | VAF 11/52 reads (21%) | catalogued as COSV58302291; called by muse, mutect2, varscan2
- TLN1 | c.5249C>T p.S1750F | Missense Mutation (SNP) | VAF 201/255 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59208970; called by muse, mutect2, varscan2
- TLR2 | c.1913A>C p.N638T | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV52607022; called by muse, mutect2, varscan2
- TMEM132A | c.2740C>T p.P914S (on ENST00000453848 / NM_178031.3; = p.P915S on NM_017870.4) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV50010121; called by muse, mutect2, varscan2
- TMF1 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 103/272 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.276); catalogued as rs748334862, COSV68374758; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 88/148 reads (59%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV59528020, COSV59528089; called by muse, mutect2, varscan2
- TNIK | c.693C>T p.P231= | Splice Region (SNP) | VAF 10/28 reads (36%) | catalogued as COSV52686599; called by muse, mutect2, varscan2
- TPP1 | c.378C>T p.I126= | Splice Region (SNP) | VAF 68/176 reads (39%) | catalogued as COSV54994565; called by muse, mutect2, varscan2
- TRIM37 | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV51885675; called by muse, mutect2, varscan2
- TTC31 | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52036063; called by muse, mutect2, varscan2
- TTC7A | c.1287+1G>T p.X429_splice | Splice Site (SNP) | VAF 8/57 reads (14%) | catalogued as rs771067566, COSV55412576; called by muse, mutect2, varscan2
- TTN | c.23119G>A p.E7707K (on ENST00000591111; = p.E6780K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 104/390 reads (27%) | PolyPhen benign (0.041); catalogued as rs1449702397, COSV60158548; called by muse, mutect2, varscan2
- UBASH3A | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145463901, COSV52313259; called by muse, mutect2, varscan2
- UBE3B | c.2899G>A p.D967N | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as rs1156522771, COSV100688460; called by muse, mutect2, varscan2
- UBTF | c.1522C>T p.R508W | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1207491061, COSV57186978; called by muse, mutect2, varscan2
- UGT2A3 | c.1305T>G p.S435= | Splice Region (SNP) | VAF 25/120 reads (21%) | catalogued as COSV52360828; called by muse, mutect2, varscan2
- UGT2B4 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs1207803837, COSV59318186; called by muse, mutect2, varscan2
- UHRF1BP1 | c.2443G>A p.D815N | Missense Mutation (SNP) | VAF 56/323 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV51957325; called by muse, mutect2, varscan2
- VEGFA | c.593A>G p.D198G (on ENST00000523873 / NM_001171623.1; = p.D361G on NM_003376.6) | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57878894; called by muse, mutect2, varscan2
- VNN1 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs536713084, COSV63390224; called by muse, mutect2, varscan2
- VSTM1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.792); catalogued as COSV58075521; called by muse, mutect2, varscan2
- WNK4 | c.2275G>A p.E759K | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV55906524, COSV99077569; called by muse, mutect2, varscan2
- XIRP1 | c.3797G>A p.G1266E | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as rs571199422, COSV61138590, COSV61139318; called by muse, mutect2, varscan2
- ZAN | c.932G>A p.G311E | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61810980, COSV61814911; called by muse, mutect2
- ZBTB11 | c.1216C>T p.H406Y | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV57245723; called by muse, mutect2, varscan2
- ZC3H7A | c.1277C>T p.P426L | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.18); catalogued as rs1254556597, COSV63270171; called by muse, mutect2, varscan2
- ZFHX3 | c.9149C>T p.S3050F | Missense Mutation (SNP) | VAF 55/195 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as COSV51723902; called by muse, mutect2, varscan2
- ZFHX4 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745459061, COSV51455764; called by muse, mutect2, varscan2
- ZMAT1 | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 94/270 reads (35%) | catalogued as COSV65659098; called by muse, mutect2, varscan2
- ZMAT4 | c.564G>T p.M188I | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs1379370094, COSV52704226; called by muse, mutect2, varscan2
- ZNF208 | c.330T>A p.N110K | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.987); catalogued as COSV68108968; called by muse, mutect2
- ZNF362 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.994); catalogued as COSV65031615; called by muse, mutect2, varscan2
- ZNF44 | c.433C>T p.P145S (on ENST00000356109 / NM_001164276.2; = p.P97S on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/227 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.276); catalogued as COSV61135207; called by muse, mutect2, varscan2
- ZNF644 | c.2327C>T p.S776L | Missense Mutation (SNP) | VAF 93/196 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV61348557; called by muse, mutect2, varscan2
- ZNF783 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as rs372949818; called by muse, mutect2, varscan2
- ZNF793 | c.236G>T p.W79L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV71325080; called by muse, mutect2, varscan2
- ZNF81 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV58576903; called by muse, mutect2, varscan2
- ATG13 | c.318-20_345del p.X106_splice | Splice Site (DEL) | VAF 26/138 reads (19%) | called by mutect2, pindel
- BAZ1A | c.1819_1824del p.D607_L608del | In Frame Del (DEL) | VAF 56/151 reads (37%) | called by mutect2, pindel, varscan2
- MAN1A1 | c.635_641del p.G212Afs*4 | Frame Shift Del (DEL) | VAF 68/197 reads (35%) | called by mutect2, pindel, varscan2
- MCOLN2 | c.1465_1490del p.S489Dfs*14 | Frame Shift Del (DEL) | VAF 65/181 reads (36%) | called by mutect2, pindel
- PRAMEF19 | c.660G>A p.M220I | Missense Mutation (SNP) | VAF 162/484 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCC4 | c.2901C>T p.S967= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV65314488; called by muse, mutect2, varscan2
- ACAP1 | c.609C>T p.F203= | Silent (SNP) | VAF 17/23 reads (74%) | catalogued as COSV50137403; called by muse, mutect2, varscan2
- ADAM2 | c.2196A>G p.E732= | Silent (SNP) | VAF 39/158 reads (25%) | catalogued as COSV55864423; called by muse, mutect2, varscan2
- ADAT2 | c.231C>T p.I77= | Silent (SNP) | VAF 47/214 reads (22%) | catalogued as rs779333821, COSV52794889; called by muse, mutect2, varscan2
- ADGRG6 | c.963C>T p.I321= | Silent (SNP) | VAF 51/296 reads (17%) | catalogued as rs374589905; called by muse, mutect2, varscan2
- AGL | c.3288C>T p.F1096= | Silent (SNP) | VAF 109/312 reads (35%) | catalogued as COSV54054502; called by muse, mutect2, varscan2
- APPBP2 | c.1020T>C p.S340= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as COSV50027624; called by muse, mutect2, varscan2
- ARHGAP25 | c.1167C>T p.L389= (on ENST00000409202 / NM_001007231.3; = p.L381= on NM_014882.3) | Silent (SNP) | VAF 31/178 reads (17%) | catalogued as COSV54904406; called by muse, mutect2, varscan2
- ARHGEF11 | c.2901C>T p.I967= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as COSV59355659; called by muse, mutect2, varscan2
- ARSJ | c.1401C>T p.V467= | Silent (SNP) | VAF 62/131 reads (47%) | catalogued as rs756890220, COSV59538480; called by muse, mutect2, varscan2
- ASB17 | c.354A>G p.T118= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV52410959; called by muse, mutect2, varscan2
- ATM | c.2823C>T p.S941= | Silent (SNP) | VAF 62/112 reads (55%) | catalogued as COSV53751046; called by muse, mutect2, varscan2
- ATP9A | c.996C>T p.I332= | Silent (SNP) | VAF 43/147 reads (29%) | catalogued as COSV58768461; called by muse, mutect2, varscan2
- BMP3 | c.87C>T p.F29= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV51088001; called by muse, mutect2, varscan2
- C16orf78 | c.291G>A p.R97= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs1252139265, COSV54557065; called by muse, mutect2
- C2CD2 | c.1185C>T p.I395= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV61599349, COSV61599884; called by muse, mutect2, varscan2
- C8B | c.1638G>A p.G546= | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as COSV64778295; called by muse, mutect2, varscan2
- CACNA1A | c.345C>T p.L115= | Silent (SNP) | VAF 59/268 reads (22%) | catalogued as rs747917423, COSV64202225; called by muse, mutect2, varscan2
- CACNA1C | c.4116C>T p.F1372= | Silent (SNP) | VAF 33/72 reads (46%) | catalogued as COSV59737709; called by muse, mutect2, varscan2
- CAPN10 | c.924C>T p.F308= | Silent (SNP) | VAF 69/107 reads (64%) | catalogued as rs893508687, COSV54377471; called by muse, mutect2, varscan2
- CARF | c.312C>T p.I104= | Silent (SNP) | VAF 70/124 reads (56%) | catalogued as COSV57548347; called by muse, mutect2, varscan2
- CARMIL2 | c.3657G>A p.R1219= | Silent (SNP) | VAF 57/137 reads (42%) | catalogued as COSV54668634; called by muse, mutect2, varscan2
- CCDC114 | c.1914G>A p.S638= | Silent (SNP) | VAF 61/133 reads (46%) | catalogued as COSV59556759; called by muse, mutect2, varscan2
- CCDC170 | c.990C>T p.I330= | Silent (SNP) | VAF 34/104 reads (33%) | catalogued as rs377676781; called by muse, mutect2, varscan2
- CDH1 | c.2397C>T p.P799= | Silent (SNP) | VAF 41/157 reads (26%) | catalogued as COSV99931154; called by muse, mutect2, varscan2
- CHRNA9 | c.993G>A p.R331= | Silent (SNP) | VAF 73/305 reads (24%) | catalogued as COSV59574793; called by muse, mutect2, varscan2
- CIT | c.1197C>T p.S399= | Silent (SNP) | VAF 59/151 reads (39%) | catalogued as COSV55873558; called by muse, mutect2, varscan2
- CLU | c.1041C>T p.S347= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV57067218; called by muse, mutect2, varscan2
- CNOT1 | c.447C>T p.I149= | Silent (SNP) | VAF 136/352 reads (39%) | catalogued as COSV57764250, COSV57778779; called by muse, mutect2, varscan2
- COL6A3 | c.2698C>T p.L900= | Silent (SNP) | VAF 58/112 reads (52%) | catalogued as COSV55095587; called by muse, mutect2, varscan2
- CPA3 | c.1014A>T p.L338= | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as COSV56045868; called by muse, mutect2, varscan2
- CPSF3 | c.216C>T p.F72= | Silent (SNP) | VAF 79/224 reads (35%) | catalogued as COSV53010358; called by muse, mutect2, varscan2
- CTDP1 | c.1833C>T p.Y611= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV50005453; called by muse, mutect2, varscan2
- CWC22 | c.894G>A p.K298= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as COSV55429828; called by muse, mutect2, varscan2
- DENND4B | c.3012C>T p.D1004= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs756087625, COSV63410193; called by muse, mutect2
- DIAPH1 | c.2178C>T p.I726= | Silent (SNP) | VAF 20/30 reads (67%) | catalogued as rs1336061221, COSV53884752; called by muse, mutect2, varscan2
- DNAAF6 | c.279G>A p.E93= | Silent (SNP) | VAF 27/39 reads (69%) | catalogued as COSV60496223; called by muse, mutect2, varscan2
- DPP9 | c.2157C>T p.I719= (on ENST00000598800; = p.I748= on NM_139159.5) | Silent (SNP) | VAF 28/107 reads (26%) | catalogued as rs757600372, COSV53592258; called by muse, mutect2, varscan2
- DROSHA | c.2610C>T p.I870= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as COSV60778452; called by muse, mutect2, varscan2
- DSCAM | c.1887C>T p.T629= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV68029884; called by muse, mutect2, varscan2
- DSCAML1 | c.2754C>T p.D918= (on ENST00000321322; = p.D858= on NM_020693.4) | Silent (SNP) | VAF 38/70 reads (54%) | catalogued as COSV58395353; called by muse, mutect2, varscan2
- DUSP16 | c.903G>A p.Q301= | Silent (SNP) | VAF 75/199 reads (38%) | catalogued as COSV53808467; called by muse, mutect2, varscan2
- EMCN | c.585G>T p.V195= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV56460697; called by muse, mutect2, varscan2
- ERCC6 | c.789C>T p.I263= | Silent (SNP) | VAF 99/163 reads (61%) | catalogued as rs753301921, COSV63390946; called by muse, mutect2, varscan2
- F11 | c.918G>A p.L306= | Silent (SNP) | VAF 107/267 reads (40%) | catalogued as COSV53007708; called by muse, mutect2, varscan2
- FAM155A | c.816C>T p.D272= | Silent (SNP) | VAF 60/106 reads (57%) | catalogued as COSV101026578; called by muse, mutect2, varscan2
- FAM221A | c.603G>A p.A201= | Silent (SNP) | VAF 38/352 reads (11%) | catalogued as rs930694215, COSV61387540; called by muse, mutect2, varscan2
- FAM91A1 | c.1480C>T p.L494= | Silent (SNP) | VAF 164/345 reads (48%) | catalogued as COSV58237885; called by muse, mutect2, varscan2
- FCAR | c.714C>T p.L238= | Silent (SNP) | VAF 206/476 reads (43%) | catalogued as rs944126574, COSV62029084; called by muse, mutect2, varscan2
- FHOD1 | c.3003G>A p.Q1001= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV50763176; called by muse, mutect2, varscan2
- FLG | c.3762G>A p.Q1254= | Silent (SNP) | VAF 87/465 reads (19%) | catalogued as rs138551548; called by muse, mutect2, varscan2
- FLII | c.2385G>A p.L795= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as rs1385701495, COSV57498958; called by muse, mutect2, varscan2
- FLNB | c.6591G>T p.R2197= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV55884325; called by muse, mutect2, varscan2
- FSIP2 | c.16848G>A p.R5616= | Silent (SNP) | VAF 50/236 reads (21%) | catalogued as COSV58090642; called by muse, mutect2, varscan2
- GALNT6 | c.636C>T p.I212= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs1343666979, COSV62542578; called by muse, mutect2, varscan2
- GBGT1 | c.384C>T p.F128= | Silent (SNP) | VAF 31/43 reads (72%) | catalogued as rs1017203892, COSV64410399; called by muse, mutect2, varscan2
- GDPD5 | c.534C>T p.I178= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs761322326, COSV61128578; called by muse, mutect2
- GIMAP1 | c.372C>T p.F124= | Silent (SNP) | VAF 48/113 reads (42%) | catalogued as COSV56187085; called by muse, mutect2, varscan2
- GIMAP2 | c.573G>A p.Q191= | Silent (SNP) | VAF 184/404 reads (46%) | catalogued as COSV56235663; called by muse, mutect2, varscan2
- GLDC | c.3048G>A p.K1016= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV58681742; called by muse, mutect2, varscan2
- GRIN2A | c.1317C>T p.F439= | Silent (SNP) | VAF 30/121 reads (25%) | catalogued as rs752012396, COSV58030496; called by muse, mutect2, varscan2
- HEPHL1 | c.2835G>A p.K945= | Silent (SNP) | VAF 88/241 reads (37%) | catalogued as COSV59893473; called by muse, mutect2, varscan2
- HIP1R | c.2314C>T p.L772= | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as COSV53442665; called by muse, mutect2, varscan2
- HMSD | c.261G>A p.T87= | Silent (SNP) | VAF 33/114 reads (29%) | catalogued as rs1384875525, COSV101282944, COSV68816978; called by muse, mutect2, varscan2
- HOXC9 | c.672G>A p.E224= | Silent (SNP) | VAF 27/162 reads (17%) | catalogued as rs1422605510, COSV57717009; called by muse, mutect2, varscan2
- HYDIN | c.7677G>A p.K2559= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV59261757; called by muse, mutect2
- ITK | c.180C>T p.I60= | Silent (SNP) | VAF 40/69 reads (58%) | catalogued as COSV70063364; called by muse, mutect2, varscan2
- KAZN | c.783C>T p.A261= | Silent (SNP) | VAF 30/103 reads (29%) | catalogued as COSV63208819; called by muse, mutect2, varscan2
- KCND3 | c.1725G>A p.T575= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as rs148478583; called by muse, mutect2, varscan2
- KIAA1841 | c.216C>T p.S72= | Silent (SNP) | VAF 51/165 reads (31%) | catalogued as COSV54376179; called by muse, mutect2, varscan2
- KIR3DL1 | c.840C>T p.F280= | Silent (SNP) | VAF 49/239 reads (21%) | catalogued as rs765913238, COSV58487495; called by muse, varscan2
- KRTAP5-9 | c.87G>A p.R29= | Silent (SNP) | VAF 35/224 reads (16%) | catalogued as COSV73200215; called by muse, mutect2, varscan2
- LBP | c.705C>T p.A235= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as COSV54140885; called by muse, mutect2, varscan2
- LIMS2 | c.930G>A p.E310= (on ENST00000355119 / NM_001161403.3; = p.E334= on NM_017980.4) | Silent (SNP) | VAF 127/369 reads (34%) | catalogued as COSV61443582; called by muse, mutect2, varscan2
- LRRIQ1 | c.1023G>A p.E341= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV67833215; called by muse, mutect2, varscan2
- LY9 | c.441C>T p.T147= | Silent (SNP) | VAF 79/188 reads (42%) | catalogued as COSV54435314; called by muse, mutect2, varscan2
- MADD | c.1059C>T p.I353= | Silent (SNP) | VAF 49/121 reads (40%) | catalogued as COSV60625944; called by muse, mutect2, varscan2
- MAP3K19 | c.975A>G p.E325= | Silent (SNP) | VAF 36/101 reads (36%) | catalogued as rs1024213808, COSV59640265; called by muse, mutect2, varscan2
- MARCHF9 | c.798G>A p.K266= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as rs773033046, COSV56985625; called by muse, mutect2, varscan2
- MCM8 | c.903G>A p.Q301= | Silent (SNP) | VAF 53/137 reads (39%) | catalogued as COSV54515655; called by muse, mutect2, varscan2
- MRPS33 | c.195C>T p.L65= | Silent (SNP) | VAF 134/298 reads (45%) | catalogued as COSV61341469; called by muse, mutect2, varscan2
- MUC17 | c.8916T>G p.A2972= | Silent (SNP) | VAF 135/1192 reads (11%) | catalogued as COSV60293488; called by muse, mutect2, varscan2
- MYBPH | c.894C>T p.L298= | Silent (SNP) | VAF 63/188 reads (34%) | catalogued as COSV55143023; called by muse, mutect2, varscan2
- MYH1 | c.1177C>T p.L393= | Silent (SNP) | VAF 62/271 reads (23%) | catalogued as COSV56851515; called by muse, mutect2, varscan2
- MYO7B | c.1131C>T p.I377= | Silent (SNP) | VAF 52/146 reads (36%) | catalogued as COSV67348991; called by muse, mutect2, varscan2
- MYOM1 | c.3222C>T p.F1074= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs374513799; called by muse, mutect2, varscan2
- NAT8L | c.705C>T p.F235= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs752594380, COSV59051635; called by muse, mutect2, varscan2
- NCOA6 | c.1893C>T p.S631= | Silent (SNP) | VAF 62/171 reads (36%) | catalogued as COSV62865288; called by muse, mutect2, varscan2
- NELL2 | c.2007C>T p.F669= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs772079522, COSV61569372; called by muse, varscan2
- NPAP1 | c.1587C>T p.F529= | Silent (SNP) | VAF 134/240 reads (56%) | catalogued as rs760465166, COSV61508444; called by muse, mutect2, varscan2
- NPC1L1 | c.2259T>A p.S753= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as COSV56926726; called by muse, mutect2, varscan2
- NRP1 | c.1674C>T p.S558= | Silent (SNP) | VAF 55/190 reads (29%) | catalogued as COSV55170314; called by muse, mutect2, varscan2
- NRXN2 | c.1290G>A p.G430= | Silent (SNP) | VAF 63/158 reads (40%) | catalogued as COSV55456689; called by muse, mutect2, varscan2
- OAS3 | c.705C>T p.F235= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs529049022, COSV57445020; called by muse, mutect2, varscan2
- OR2A12 | c.90C>T p.F30= | Silent (SNP) | VAF 87/234 reads (37%) | catalogued as COSV68821675; called by muse, mutect2, varscan2
- OR2B11 | c.753C>T p.I251= | Silent (SNP) | VAF 59/174 reads (34%) | catalogued as rs780372908, COSV59510053; called by muse, mutect2, varscan2
- OR2G6 | c.318G>T p.G106= | Silent (SNP) | VAF 41/171 reads (24%) | catalogued as rs756883041, COSV58574993; called by muse, mutect2, varscan2
- OR2W3 | c.108C>T p.L36= | Silent (SNP) | VAF 66/183 reads (36%) | catalogued as COSV64457348; called by muse, mutect2, varscan2
- OR4B1 | c.537C>T p.L179= | Silent (SNP) | VAF 80/231 reads (35%) | catalogued as COSV58883213; called by muse, mutect2, varscan2
- OR52L1 | c.309C>T p.L103= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV59987901; called by muse, mutect2, varscan2
- OR5I1 | c.150G>A p.L50= | Silent (SNP) | VAF 42/122 reads (34%) | catalogued as COSV56887272; called by muse, mutect2, varscan2
- OR6C65 | c.273C>A p.S91= | Silent (SNP) | VAF 63/176 reads (36%) | catalogued as COSV65568867; called by muse, mutect2, varscan2
- PCDHB5 | c.1152C>T p.I384= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV99167592; called by muse, mutect2, varscan2
- PDGFRB | c.201G>A p.Q67= | Silent (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2
- PDS5A | c.2061A>T p.L687= | Silent (SNP) | VAF 63/147 reads (43%) | catalogued as COSV57827587; called by muse, mutect2, varscan2
- PITX2 | c.399C>T p.F133= (on ENST00000354925 / NM_001204397.1; = p.F140= on NM_000325.6) | Silent (SNP) | VAF 22/129 reads (17%) | catalogued as COSV60741404; called by muse, mutect2, varscan2
- PRAG1 | c.111G>A p.R37= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs1388862428, COSV58163308; called by muse, mutect2, varscan2
- PRDM14 | c.612C>T p.F204= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs369845893; called by muse, mutect2, varscan2
- PRRC2A | c.2388C>T p.F796= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as rs1294917626; called by muse, mutect2
- PRSS55 | c.411G>A p.K137= | Silent (SNP) | VAF 54/218 reads (25%) | catalogued as rs200901473, COSV60808672; called by muse, mutect2, varscan2
- PSORS1C1 | c.201G>A p.K67= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV52535918; called by muse, mutect2, varscan2
- PTPRN | c.900G>A p.G300= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as COSV55349518; called by muse, mutect2, varscan2
- RADIL | c.87C>T p.S29= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs563960642, COSV68202639; called by muse, mutect2, varscan2
- RAI2 | c.1419C>T p.S473= | Silent (SNP) | VAF 277/366 reads (76%) | catalogued as rs1351856699, COSV58964484, COSV58964693; called by muse, mutect2, varscan2
- RBSN | c.1236G>A p.E412= | Silent (SNP) | VAF 33/96 reads (34%) | catalogued as COSV99514968; called by muse, mutect2, varscan2
- RGS7 | c.1246C>A p.R416= | Silent (SNP) | VAF 49/162 reads (30%) | catalogued as COSV100464250; called by muse, mutect2, varscan2
- RPH3AL | c.165C>T p.I55= | Silent (SNP) | VAF 65/91 reads (71%) | catalogued as COSV58738835; called by muse, mutect2
- SACS | c.10308C>T p.I3436= | Silent (SNP) | VAF 12/157 reads (8%) | catalogued as COSV66540086; called by muse, mutect2
- SBF1 | c.3900C>T p.P1300= | Silent (SNP) | VAF 4/8 reads (50%) | called by muse, varscan2
- SEMA5B | c.3321C>T p.I1107= | Silent (SNP) | VAF 39/120 reads (33%) | catalogued as COSV52101532; called by muse, mutect2, varscan2
- SEPTIN8 | c.1128C>T p.V376= | Silent (SNP) | VAF 84/126 reads (67%) | catalogued as COSV51524399; called by muse, mutect2, varscan2
- SERPINI2 | c.279C>T p.F93= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as COSV52987094; called by muse, mutect2, varscan2
- SERTAD2 | c.168G>A p.E56= | Silent (SNP) | VAF 100/293 reads (34%) | catalogued as rs533662041, COSV57640649; called by muse, mutect2, varscan2
- SLC10A6 | c.168G>A p.R56= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV56722164; called by muse, mutect2, varscan2
- SLC34A2 | c.333C>T p.F111= | Silent (SNP) | VAF 20/101 reads (20%) | catalogued as rs144239727, COSV101158249, COSV65941106; called by muse, mutect2, varscan2
- SLC39A5 | c.417C>T p.L139= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as COSV57192322; called by muse, mutect2, varscan2
- SLC8A1 | c.210T>G p.S70= | Silent (SNP) | VAF 12/195 reads (6%) | catalogued as COSV60486477; called by muse, mutect2
- SMPD2 | c.1158G>A p.Q386= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as COSV99237712; called by muse, mutect2, varscan2
- SNRK | c.744G>T p.R248= | Silent (SNP) | VAF 132/395 reads (33%) | catalogued as COSV56069199; called by muse, mutect2, varscan2
- SPIDR | c.357G>A p.Q119= | Silent (SNP) | VAF 27/81 reads (33%) | called by muse, mutect2, varscan2
- SPRR2G | c.90G>A p.P30= | Silent (SNP) | VAF 52/151 reads (34%) | catalogued as rs1288336821, COSV64203185; called by muse, mutect2, varscan2
- STON1 | c.1248C>T p.S416= | Silent (SNP) | VAF 37/240 reads (15%) | catalogued as rs1430899606, COSV59132830; called by muse, mutect2, varscan2
- SYNE1 | c.23775G>A p.K7925= (on ENST00000367255 / NM_182961.4; = p.K7854= on NM_033071.3) | Silent (SNP) | VAF 33/187 reads (18%) | catalogued as COSV55022085; called by muse, mutect2, varscan2
- TBL3 | c.414C>T p.I138= | Silent (SNP) | VAF 48/95 reads (51%) | catalogued as rs778330440, COSV60342094; called by muse, mutect2, varscan2
- TF | c.93G>A p.S31= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as rs1291195506, COSV99395316; called by muse, mutect2, varscan2
- TLR9 | c.123C>T p.G41= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as rs1181833524, COSV59726740; called by muse, mutect2, varscan2
- TMEM104 | c.1068C>T p.F356= | Silent (SNP) | VAF 69/268 reads (26%) | catalogued as rs1396983794, COSV59110279; called by muse, mutect2, varscan2
- TRABD2A | c.1086G>A p.G362= (on ENST00000409520 / NM_001277053.2; = p.G313= on NM_001080824.3) | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV52849450; called by muse, mutect2, varscan2
- TRIM10 | c.213C>T p.P71= | Silent (SNP) | VAF 116/316 reads (37%) | catalogued as COSV64989861, COSV64989869; called by muse, mutect2, varscan2
- TRMT1 | c.1941C>T p.P647= | Silent (SNP) | VAF 58/284 reads (20%) | catalogued as COSV53400323; called by muse, mutect2, varscan2
- TRRAP | c.994C>T p.L332= | Silent (SNP) | VAF 160/304 reads (53%) | catalogued as rs782566917, COSV62847674; called by muse, mutect2, varscan2
- TTN | c.74289C>T p.T24763= (on ENST00000591111; = p.T17339= on NM_003319.4) | Silent (SNP) | VAF 59/232 reads (25%) | catalogued as rs778020953, COSV59916380; ClinVar: likely benign; called by muse, mutect2, varscan2
- UBE3B | c.2898G>A p.P966= | Silent (SNP) | VAF 44/152 reads (29%) | catalogued as rs748279232, COSV100688457; called by muse, mutect2, varscan2
- UEVLD | c.342C>T p.L114= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as COSV55578760; called by muse, mutect2, varscan2
- UGT2B28 | c.1569G>A p.G523= | Silent (SNP) | VAF 24/117 reads (21%) | catalogued as COSV59431277; called by muse, mutect2, varscan2
- UGT2B4 | c.705C>T p.F235= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as COSV100522654, COSV59318177; called by muse, mutect2, varscan2
- ULBP2 | c.258C>T p.A86= | Silent (SNP) | VAF 102/359 reads (28%) | catalogued as COSV66265647; called by muse, varscan2
- UNC79 | c.3351C>T p.T1117= (on ENST00000393151 / NM_001346218.2; = p.T940= on NM_020818.5) | Silent (SNP) | VAF 35/66 reads (53%) | catalogued as COSV56395124, COSV99830089; called by muse, mutect2, varscan2
- UNC79 | c.6306G>A p.T2102= (on ENST00000393151 / NM_001346218.2; = p.T1925= on NM_020818.5) | Silent (SNP) | VAF 134/378 reads (35%) | catalogued as rs779988693, COSV56390148; called by muse, varscan2
- USHBP1 | c.855C>T p.P285= | Silent (SNP) | VAF 116/246 reads (47%) | catalogued as COSV53104544; called by muse, mutect2, varscan2
- VPS54 | c.1896C>T p.S632= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as rs746337890, COSV55442240; called by muse, mutect2
- WNK4 | c.3510G>A p.Q1170= | Silent (SNP) | VAF 31/58 reads (53%) | catalogued as COSV55906538; called by muse, mutect2, varscan2
- ZBTB12 | c.714C>T p.S238= | Silent (SNP) | VAF 38/96 reads (40%) | catalogued as COSV64993972; called by muse, mutect2, varscan2
- ZBTB3 | c.66C>T p.F22= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV67361445; called by muse, mutect2, varscan2
- ZNF229 | c.1404G>A p.K468= | Silent (SNP) | VAF 40/83 reads (48%) | catalogued as COSV52162075; called by muse, mutect2, varscan2
- ZNF320 | c.51C>T p.F17= | Silent (SNP) | VAF 14/239 reads (6%) | called by muse, mutect2
- ZNF362 | c.639C>T p.P213= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs1004389206, COSV65031618; called by muse, mutect2, varscan2
- ZNF581 | c.270C>T p.P90= | Silent (SNP) | VAF 48/101 reads (48%) | catalogued as rs556294832, COSV54401552, COSV54402161; called by muse, mutect2, varscan2
- ZNF888 | c.51C>T p.F17= | Silent (SNP) | VAF 24/380 reads (6%) | catalogued as COSV101480810; called by muse, mutect2
- AC073310.1 | n.308C>T | RNA (SNP) | VAF 234/563 reads (42%) | called by muse, mutect2, varscan2
- EEF1D | c.-7-2876C>T | Intron (SNP) | VAF 10/24 reads (42%) | catalogued as rs1237552787, COSV57820946; called by muse, mutect2, varscan2
- FOLH1B | n.2102G>A | RNA (SNP) | VAF 63/165 reads (38%) | called by muse, mutect2, varscan2
- GP6 | c.*349C>T | 3'UTR (SNP) | VAF 25/99 reads (25%) | catalogued as COSV100117373; called by muse, mutect2, varscan2
- GP6 | c.*348C>T | 3'UTR (SNP) | VAF 25/101 reads (25%) | catalogued as rs745968195, COSV100117374; called by muse, mutect2, varscan2
- KCNK12 | c.*8534C>T | 3'UTR (SNP) | VAF 13/33 reads (39%) | catalogued as COSV59946110; called by muse, mutect2, varscan2
- LINC02145 | n.137C>T | RNA (SNP) | VAF 76/127 reads (60%) | catalogued as rs528308095; called by muse, mutect2, varscan2
- PKD1L2 | n.2754C>T | RNA (SNP) | VAF 4/19 reads (21%) | catalogued as rs1056261841; called by muse, mutect2, varscan2
- PSG5 | c.431-2780G>A | Intron (SNP) | VAF 197/521 reads (38%) | catalogued as COSV100742547; called by muse, mutect2, varscan2
- SLC5A12 | c.-2A>G | 5'UTR (SNP) | VAF 43/216 reads (20%) | catalogued as COSV99744326; called by muse, mutect2, varscan2
- SPTB | c.6345+34G>A | Intron (SNP) | VAF 98/250 reads (39%) | catalogued as COSV100731075; called by muse, mutect2, varscan2
- SPTB | c.6345+33G>A | Intron (SNP) | VAF 98/251 reads (39%) | catalogued as COSV100731076; called by muse, mutect2, varscan2
- TTN | c.10360+3642G>A | Intron (SNP) | VAF 94/181 reads (52%) | catalogued as rs1360243415, COSV100592436; called by muse, mutect2, varscan2
- TTN | c.10360+2862C>T | Intron (SNP) | VAF 118/215 reads (55%) | catalogued as COSV100592438; called by muse, mutect2, varscan2
